Somatic mutation profile of tumor specimen 0DW6BS from CCDI case PBCNVH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 2.9 years (1,058 days).
Specimen 0DW6BS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9ae094f-fb10-42d4-a550-b3a433726cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW6B4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ad8caca-94bf-4665-a81a-23fc1ec6f137

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, 5'Flank 1, Intron 1, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 430/1030 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPRA | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 240/643 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191821659, COSV53789268; called by muse, mutect2, varscan2
- TRAF3 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 463/1612 reads (29%) | catalogued as COSV61024910, COSV61027276; called by muse, mutect2, varscan2
- CACNA2D3 | c.809T>G p.L270R | Missense Mutation (SNP) | VAF 470/1256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPA4 | c.105C>G p.D35E | Missense Mutation (SNP) | VAF 203/652 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EML4 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 508/2367 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- L3MBTL1 | c.2129G>A p.G710E (on ENST00000418998 / NM_001377303.1; = p.G620E on NM_015478.7) | Missense Mutation (SNP) | VAF 273/722 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- LRRC75B | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 180/457 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SV2C | c.1269A>T p.R423S | Missense Mutation (SNP) | VAF 221/711 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF836 | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 58/1988 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.491); called by muse, mutect2
- KCNH3 | c.1015C>T p.L339= | Silent (SNP) | VAF 244/661 reads (37%) | called by muse, mutect2, varscan2
- NELL1 | c.2346G>A p.T782= | Silent (SNP) | VAF 374/943 reads (40%) | catalogued as rs369702287, COSV54270618; called by muse, mutect2, varscan2
- SPPL2B | c.549G>T p.V183= | Silent (SNP) | VAF 316/1172 reads (27%) | called by muse, mutect2, varscan2
- TRIML2 | c.162G>C p.G54= | Silent (SNP) | VAF 319/784 reads (41%) | called by muse, mutect2, varscan2
- XIRP2 | c.139C>A p.R47= (on ENST00000628543; = p.R222= on NM_152381.6) | Silent (SNP) | VAF 406/1106 reads (37%) | catalogued as rs767389886, COSV54680961; called by muse, mutect2, varscan2
- CPNE4 | chr3:132037607 C>G | 5'Flank (SNP) | VAF 492/1230 reads (40%) | called by muse, mutect2, varscan2
- EDA2R | c.*103A>T | 3'UTR (SNP) | VAF 254/381 reads (67%) | called by muse, mutect2, varscan2
- OTOG | c.2642-45A>G | Intron (SNP) | VAF 113/252 reads (45%) | catalogued as rs1165431975; called by muse, mutect2, varscan2
- VPS11 | c.-685G>T | 5'UTR (SNP) | VAF 322/862 reads (37%) | called by muse, mutect2, varscan2
